Surgical pathology report (de-identified scan), TCGA case TCGA-ET-A25J, project TCGA-THCA (Thyroid Carcinoma), tissue source site Johns Hopkins, specimen TCGA-ET-A25J-01A (Primary Tumor).

[page 1 of 2]
FINAL DIAGNOSIS -----

1) TOTAL THYROID (THYROIDECTOMY):

SPECIMEN TYPE: Total thyroidectomy

1CD-0-3

TUMOR SITE: Right lobe

Carcinoma, papillary, thyroid 8260/3

Site: thyroid C739

HISTOLOGIC TYPE: Papillary carcinoma

for
5/4/11

TUMOR SIZE (LARGEST NODULE):

Greatest dimension: 2.5 cm

FOCALITY: Unifocal

LYMPH NODES (ALL PARTS):

Metastatic carcinoma in 2 of 18 lymph nodes

EXTENT OF INVASION (STAGING) PRIMARY TUMOR:

pT2: Tumor >2.0 cm but less than or equal to 4.0 cm limited to thyroid

REGIONAL LYMPH NODES:

pN1a: Nodal metastasis to Level VI (pretracheal, paratracheal, prelaryngeal/Delphian) nodes

DISTANT METASTASIS:

pMx: Cannot be assessed

MARGINS: Margins are uninvolved

VENOUS/LYMPHATIC INVASION: Absent

ADDITIONAL PATHOLOGIC FINDINGS:

One benign parathyroid gland

[page 2 of 2]
GROSS DESCRIPTION

PART #1: TOTAL THYROID

Dictated:

The specimen is received fresh labeled with the patient's name, xxxx, and designated "Total Thyroid, Stitch Marks Right Thyroid Tumor." The specimen consists of a grossly identifiable thyroid measuring 7.4 x 5.3 x 2.0 cm and weighing 16.37 grams. The anterior is inked orange and the posterior inked black. Serial sectioning reveals a 2.5 x 2.4 x 1.5 cm tumor in the right middle lobe, with a tan to white focally hemorrhagic and necrotic appearance. The specimen is serially sectioned and submitted in its entirety. There is also a 1.1 x 1.1 x 1.0 cm piece of fibroadipose tissue. Blunt dissection reveals seven (7) potential lymph nodes. The remainder of the fat is submitted in its entirety.

SUMMARY OF SECTIONS :

- 1 - A - 3 (LEFT INFERIOR MARGIN)
- 1 - B - 2 (LEFT, SERIALY SECTIONED FROM INFERIOR TO SUPERIOR)
- 1 - C - 2 (LEFT LOBE)
- 1 - D - 4 (LEFT SUPERIOR MARGIN)
- 1 - E - M (ISTHMUS)
- 1 - F - 6 (RIGHT INFERIOR MARGIN)
- 1 - G - 2 (RIGHT LOBE)
- 1 - H - 2 (RIGHT LOBE)
- 1 - I - 2 (RIGHT INFERIOR TUMOR)
- 1 - J - 2 (RIGHT TUMOR)
- 1 - K - M (RIGHT LOBE SUPERIOR ASPECT OF TUMOR AND SUPERIOR MARGIN)
- 1 - L - 7 (SEVEN POTENTIAL LYMPH NODES)
- 1 - M - M (REMAINING FAT)
- 13 - TOTAL - MULTIPLE

Source: NCI Genomic Data Commons file 88c9fb98-c916-4be1-8ee8-2d06b1168919 (TCGA-ET-A25J.EC2F28C3-6E69-4BCD-B08A-54FD4B2F9603.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).